Somatic mutation profile of tumor specimen C3N-02588-01 (aliquot CPT0148180010) from CPTAC case C3N-02588, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 69.1 years (25,225 days).
Specimen C3N-02588-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78caa141-6d67-49c8-8d19-4afc929b29be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02588-71 (Blood Derived Normal), aliquot CPT0148210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8c45523-b1df-4d28-a070-6116949e345e

The open-access MAF lists 71 somatic variants for this specimen: 52 protein-altering or splice-affecting, 10 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 10, Intron 7, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 183/769 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP24 | c.1964T>G p.M655R (on ENST00000395184 / NM_001025616.3; = p.M562R on NM_031305.3) | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99982286; called by muse, mutect2, varscan2
- ARHGEF26 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 287/1124 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV62846076; called by muse, mutect2, varscan2
- ARRDC4 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as rs761972396; called by muse, mutect2
- CERKL | c.453G>A p.W151* | Nonsense Mutation (SNP) | VAF 32/178 reads (18%) | catalogued as rs746595127; called by muse, mutect2, varscan2
- DENND2D | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 16/223 reads (7%) | catalogued as COSV62959966; called by muse, mutect2
- EYA1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 87/490 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); catalogued as rs757399419; called by muse, mutect2, varscan2
- GDE1 | c.953A>G p.Y318C | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1436465969, COSV54904522; called by muse, mutect2, varscan2
- GRM5 | c.1231C>A p.L411I | Missense Mutation (SNP) | VAF 20/720 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59629023; called by muse, mutect2
- GRM7 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 76/374 reads (20%) | catalogued as COSV63143424; called by muse, mutect2, varscan2
- IL32 | c.398C>T p.S133F (on ENST00000396890 / NM_001308078.4; = p.S87F on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.307); catalogued as rs768089141, COSV50404514; called by muse, mutect2
- IRAG1 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as COSV101351063; called by muse, mutect2
- MET | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 74/422 reads (18%) | catalogued as rs369705803, COSV59257921, COSV59269561; called by muse, mutect2, varscan2
- MUC5B | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs892666181; called by muse, mutect2
- NTN3 | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs775870554; called by muse, mutect2, varscan2
- SERAC1 | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1033568259, COSV65596799; called by muse, mutect2, varscan2
- SNX13 | c.2852C>T p.A951V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.009); catalogued as rs966638937; called by muse, mutect2, varscan2
- STRC | c.4729C>T p.R1577W | Missense Mutation (SNP) | VAF 50/604 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs765170913; called by muse, mutect2
- SULT1C2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 19/339 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs969530695, COSV52264506; called by muse, mutect2
- UNK | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs75277629, COSV53145158; called by muse, mutect2, varscan2
- WNT9A | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1346833153; called by muse, mutect2, varscan2
- AASDH | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- AHNAK | c.5053C>T p.P1685S | Missense Mutation (SNP) | VAF 122/745 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ALK | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 141/690 reads (20%) | called by muse, mutect2, varscan2
- ANO10 | c.125A>T p.K42I | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.284); called by muse, mutect2
- ATP6V1E1 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2
- CCDC102A | c.585+1G>T p.X195_splice | Splice Site (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- CCDC171 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- CD79B | c.428T>G p.M143R | Missense Mutation (SNP) | VAF 150/895 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- CDH22 | c.772T>C p.S258P | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDKL5 | c.2948C>T p.T983I | Missense Mutation (SNP) | VAF 64/355 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIR1 | c.38A>T p.D13V | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CLSTN2 | c.2324A>G p.N775S | Missense Mutation (SNP) | VAF 223/476 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CNGA2 | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 108/319 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH2 | c.4273G>T p.D1425Y | Missense Mutation (SNP) | VAF 98/422 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- DNAH8 | c.68G>C p.R23P | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FLAD1 | c.1357A>G p.I453V | Missense Mutation (SNP) | VAF 91/416 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GABRA1 | c.409del p.H137Tfs*3 | Frame Shift Del (DEL) | VAF 119/705 reads (17%) | called by mutect2, pindel, varscan2
- GRID2IP | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- INF2 | c.1736_1737del p.X579_splice | Splice Site (DEL) | VAF 40/201 reads (20%) | called by pindel, varscan2
- INF2 | c.2112C>G p.F704L | Missense Mutation (SNP) | VAF 76/382 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- MMP12 | c.270_283del p.G93Pfs*23 | Frame Shift Del (DEL) | VAF 97/658 reads (15%) | called by mutect2, pindel, varscan2
- MYT1 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 54/448 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NCOA6 | c.1215G>T p.K405N | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NFRKB | c.3613A>G p.I1205V (on ENST00000446488 / NM_001143835.2; = p.I1230V on NM_006165.3) | Missense Mutation (SNP) | VAF 78/365 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NTN3 | c.289T>A p.S97T | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R21 | c.347_350del p.I116Kfs*24 | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | called by pindel, varscan2
- PRSS36 | c.782C>G p.T261S | Missense Mutation (SNP) | VAF 142/800 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPN7 | c.1072C>A p.P358T (on ENST00000495688; = p.P397T on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- TP73 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIOBP | c.2198C>T p.S733F | Missense Mutation (SNP) | VAF 102/975 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZEB2 | c.2643C>A p.N881K | Missense Mutation (SNP) | VAF 68/366 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ACTN1 | c.375C>A p.G125= | Silent (SNP) | VAF 15/362 reads (4%) | catalogued as COSV51990442; called by muse, mutect2
- APOBR | c.1632C>A p.G544= (on ENST00000431282; = p.G553= on NM_018690.4) | Silent (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- DHRS7 | c.750C>T p.V250= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs1247983450; called by muse, mutect2, varscan2
- EXOC3L4 | c.525C>T p.F175= | Silent (SNP) | VAF 23/363 reads (6%) | catalogued as rs1387614287; called by muse, mutect2
- MED13 | c.5898T>C p.S1966= | Silent (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- PRKDC | c.11280G>A p.Q3760= | Silent (SNP) | VAF 48/614 reads (8%) | called by muse, mutect2
- RNF186 | c.543G>A p.V181= | Silent (SNP) | VAF 111/585 reads (19%) | called by muse, mutect2, varscan2
- SCAF8 | c.660C>T p.S220= | Silent (SNP) | VAF 76/319 reads (24%) | called by muse, mutect2, varscan2
- SLC40A1 | c.225G>A p.L75= | Silent (SNP) | VAF 88/565 reads (16%) | catalogued as COSV53725231; called by muse, mutect2, varscan2
- SLC4A1 | c.240C>A p.R80= | Silent (SNP) | VAF 165/936 reads (18%) | called by muse, mutect2, varscan2
- ABI3BP | c.2008+1670C>T | Intron (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- AC016705.2 | n.129T>G | RNA (SNP) | VAF 28/242 reads (12%) | called by muse, mutect2, varscan2
- CHTF8 | c.*281G>A | 3'UTR (SNP) | VAF 56/186 reads (30%) | called by muse, mutect2, varscan2
- EYS | c.1766+2565G>T | Intron (SNP) | VAF 9/126 reads (7%) | catalogued as COSV60987487; called by muse, mutect2
- LACTB2 | c.286+1001G>T | Intron (SNP) | VAF 137/887 reads (15%) | called by muse, mutect2, varscan2
- LIPC | c.89-43495C>T | Intron (SNP) | VAF 29/275 reads (11%) | called by muse, mutect2, varscan2
- RBM3 | c.211-72_211-69dup | Intron (INS) | VAF 76/429 reads (18%) | called by mutect2, pindel, varscan2
- STAG2 | c.3467+164G>A | Intron (SNP) | VAF 30/143 reads (21%) | called by muse, mutect2, varscan2
- TMEM254 | c.87+299G>T | Intron (SNP) | VAF 71/316 reads (22%) | called by muse, mutect2, varscan2
